Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7315, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7315-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date: [REDACTED]

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN FIVE LYMPH NODES (0/5).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN TWO LYMPH NODES (0/2).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATE ADENOCARCINOMA, GLEASON SCORE 4 + 3 = 7.
- B. A TERTIARY COMPONENT OF GLEASON GRADE 5 CARCINOMA IS ALSO PRESENT.
- C. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.3 CM IN ONE HISTOLOGIC SECTION.
- D. THE CARCINOMA INVOLVES 15% OF THE EXAMINED PROSTATE VOLUME.
- E. THE CARCINOMA SHOWS EVIDENCE OF ESTABLISHED EXTRACAPSULAR EXTENSION.
- F. EXTRACAPSULAR EXTENSION IS PRESENT AT ANTERIOR LEFT BASE (SLIDES 3T and 3U) AND POSTERIOR LEFT MID (SLIDE 3Z) AND POSTERIOR LEFT BASE (SLIDE 3BB).
- G. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- M. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	56.68gm
TUMOR SIZE:	Maximum dimension: 1.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	7
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 9d6e6ba3-1c64-4395-b27b-56d5909a9839 (TCGA-EJ-7315.6AFA83AC-9060-4B49-90A3-DC19824822E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).